Surgical pathology report (de-identified scan), TCGA case TCGA-29-1769, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1769-01A (Primary Tumor).

[page 1 of 4]
TCGA-29-1769

Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling NOS. [REDACTED] with suspected ovarian cancer.

GROSS EXAMINATION:

A. "Peritoneal biopsy (AF1)", received fresh for frozen section is a 0.6 x 0.4 x 0.3 cm fragment of tan-brown soft tissue. The specimen is submitted for frozen section as AF1 and the frozen section remnant is submitted in block A1.

B. "Omentum", received fresh and placed in formalin is a 21 x 17 x 4.5 cm aggregate of tan-yellow fibroadipose tissue. There are several firm ill-defined intermixed with the adipose tissue up to 6.8 cm in greatest dimension. Representative sections are submitted in blocks B1-2.

C. "Omental tumor", received fresh and placed in formalin is a 3.9 x 2.7 x 2.1 cm fragment of firm tan-brown soft tissue. Sectioning through the specimen reveals a firm tan-white cut surface. Representative sections are submitted in blocks C1-2.

D. "Rectosigmoid mass", received fresh and placed in formalin is a 6.1 x 4.3 x 2.2 cm fragment of tan-yellow soft tissue. Sectioning through the specimen reveals a minimal amount of adipose tissue with an ill-defined 6 x 2.5 x 1.7 cm firm tan-white mass. Representative sections are submitted in blocks D1-2.

E. "Right ovary tissue", received fresh and placed in formalin is a 5.1 x 3.4 x 2.5 cm ovary with adjacent 4.4 cm segment of fimbriated fallopian tube demonstrating an average diameter of 0.8 cm. The ovary is remarkable for multiple cyst up to 2.5 cm in greatest dimension with numerous papillary excrescences lining the surface. The cut surface of the ovary is remarkable for multiloculated cyst intermixed with firm tan-white solid areas of up to 1.5 cm in greatest dimension. The fallopian tube on cut surface exhibits a grossly unremarkable lumen.

BLOCK SUMMARY:

E1-2- representative of ovary

E3- representative section of ovary and fallopian tube

F. "Uterus, tube and left ovary with cervix", received fresh and placed in formalin is a 8 x 5.5 x 4.2 cm uterus with attached 5 x 3.7 x 3.1 cm left ovary and 4.6 cm segment of fimbriated fallopian tube. The external uterine surface is pink-tan smooth and glistening with scattered soft tan-brown papillary excrescences up to 1.5 cm in greatest dimension concentrated closely on the anterior surface. The external cervix is grossly unremarkable with a 0.8 cm patent os. The left ovary and fallopian tube are grossly involved multiple tan-brown papillary excrescences as well. The ovarian cut surface is remarkable for several dilated cyst the largest being hemorrhagic in appearance and 1.5 cm in greatest dimension. There are several firm tan-white solid areas within the ovary as well. The fallopian tube is sectioned to reveal a grossly unremarkable cut surface with an average diameter of 0.5 cm. The lumen is grossly patent. The uterus is bivalved to demonstrate a soft tan-brown shaggy endometrium with no discrete masses. The endocervical canal is unremarkable. Sectioning through the posterior myometrium reveals several grossly unremarkable cut surface with no lesions identified. Sectioning through the anterior uterus demonstrates a 2.2 x 1 cm mass infiltrating through the serosal surface of the myometrium just below the aforementioned serosal papillary excrescences. The mass invades 1 cm into the

[page 2 of 4]
TCGA-29-1769

anterior myometrium. The lower uterine segment and anterior and posterior surgical cut surfaces are unremarkable.

BLOCK SUMMARY:

F1-3- left ovary
F4- section of peritoneal excrescences and representative section of left fallopian tube
F5-6- representative uninvolved anterior endomyometrium
F7-8- representative of posterior endomyometrium
F9- representative posterior lower uterine segment
F10- representative of posterior cervix
F11- representative anterior cervix
F12- representative anterior lower uterine segment
F13-14- anterior endomyometrium at point of greatest involvement by mass

G. "Pelvic tumor", received fresh and placed in formalin is a 2.2 x 1.7 x 0.8 cm firm tan-white fragment of tissue. The specimen is bisected and submitted entirely in block G1.

H. "Cul de sac tumor", received fresh and placed in formalin is an 8.5 x 5.5 x 2.3 cm aggregate of tan-brown fibroadipose tissue. Sectioning through the specimen reveals multiple firm tan-white nodules up to 2.9 cm in greatest dimension. Representative sections are submitted in blocks H1-3.

I. "Diaphragm", received fresh and placed in formalin is a 14.8 x 10.5 x 3.6 cm aggregate of firm tan-brown soft tissue notable for multiple papillary excrescences covering the exterior surface. Sectioning through the specimen demonstrates a diffusely firm tan-white cut surface. Representative sections are submitted in blocks I1-4.

J. "Upper peritoneal mass", received fresh and placed in formalin is a 6.3 x 6 x 1.4 cm aggregate of tan-brown soft tissue. Sectioning through the specimen demonstrates a diffusely firm tan-white cut surface. Representative sections are submitted in blocks J1-3.

K. "Liver mass", received fresh and placed in formalin is a 3.2 x 2.4 x 1.4 cm fragment of tan-brown soft tissue. Sectioning through the specimen reveals a diffusely firm tan-white cut surface intermixed with areas of unremarkable tan-yellow adipose tissue. Representative sections are submitted in blocks K1-3.

L. "Appendix", received fresh and placed in formalin is a 5.2 cm segment of appendix with an average diameter of 0.5 cm. The exterior surface is remarkable for multiple papillary excrescences up to 0.7 cm in greatest dimension. There is 4 x 2 x 0.5 cm attached mesoappendix. The cut surface is remarkable for fibrous obliteration of the lumen. The tip is removed, bisected and placed in block L1 with the proximal margin representative sections are submitted in block L1.

M. "Rectosigmoid", received fresh and placed in formalin is an 8.2 cm segment of colon demonstrating an average diameter of 3.1 cm. The external surface is remarkable for a 3.6 x 6.8 x 1.1 cm firm tan-white mass involving the external serosa and infiltrating into the bowel wall creating a 3.2 x 2.5 x 1.2 cm cavity. In addition there are multiple papillary excrescences involving the serosa and adjacent adipose tissue. Opening the specimen demonstrates a grossly unremarkable tan-brown mucosal surface with no identifiable lesions. Sectioning through the specimen shows the aforementioned firm mass does penetrate to involve the underlying bowel wall, but does not penetrate through to the mucosa.

BLOCK SUMMARY:

M1-4- representative of mass with respect to underlying bowel wall and mucosa
M5- representative uninvolved colon
M6-7- mucosal margins

[page 3 of 4]
TCGA-29-1769

INTRA OPERATIVE CONSULTATION:

A. "Peritoneal biopsy": AF1- positive for carcinoma (I

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy, bilateral salpingo-oophorectomy, omentectomy,
multiple biopsies, partial colectomy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the [REDACTED] pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "PERITONEUM" (BIOPSY):

METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.

B. "OMENTUM" (OMENECTOMY):

METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.
LARGEST METASTASIS: 6.8 CM.

C. "OMENTAL TUMOR" (EXCISION):

METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.

D. "RECTOSIGMOID MASS" (EXCISION):

FIBROADIPOSE TISSUE WITH METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.

E. "RIGHT OVARY TISSUE" (SALPINGO-OOPHORECTOMY):

OVARY WITH SEROUS PAPILLARY ADENOCARCINOMA.

FIGO GRADE: 3 OF 3 (POORLY DIFFERENTIATED).

TUMOR SIZE: 5.1 CM.

FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

F. "UTERUS, TUBE, LEFT OVARY" (HYSTERECTOMY, SALPINGO-OOPHORECTOMY):

LEFT OVARY WITH SEROUS PAPILLARY ADENOCARCINOMA.

TUMOR SIZE: 5 CM.

FIGO GRADE: 3 OF 3 (POORLY DIFFERENTIATED).

FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

UTERUS:

[page 4 of 4]
TCGA-29-1769

ENDOMETRIUM: SECRETORY.
CERVIX: FREE OF TUMOR.
MYOMETRIUM: POSITIVE FOR SEROUS PAPILLARY CARCINOMA, INVADING FROM
SEROUSAL IMPLANTS.
SEROUSA: MULTIPLE DEPOSITS OF METASTATIC SEROUS PAPILLARY
ADENOCARCINOMA.

G. "PELVIC TUMOR" (BIOPSY):

SEROUS PAPILLARY ADENOCARCINOMA.

H. "CUL-DE-SAC TUMOR" (BIOPSY):

SEROUS PAPILLARY ADENOCARCINOMA.

I. "DIAPHRAGM" (EXCISION):

SEROUS PAPILLARY ADENOCARCINOMA.

J. "UPPER PERITONEAL MASS" (BIOPSY):

SEROUS PAPILLARY ADENOCARCINOMA.

K. "LIVER MASS" (EXCISION):

FIBROADIPOSE TISSUE WITH SEROUS PAPILLARY ADENOCARCINOMA.

L. "APPENDIX" (APPENDECTOMY):

APPENDIX WITH EXTENSIVE INVOLVEMENT BY METASTATIC SEROUS PAPILLARY
ADENOCARCINOMA.

M. "RECTOSIGMOID" (PARTIAL COLECTOMY):

SEGMENT OF COLON WITH METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.
MUCOSAL MARGINS ARE NEGATIVE FOR MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f71fda6e-b520-4fb4-abc7-87e25d94e7bc (TCGA-29-1769.67F144B3-C10B-4F96-A70B-6794D817170F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).